Somatic mutation profile of tumor specimen TARGET-30-PALEVG-01A (aliquot TARGET-30-PALEVG-01A-01W) from TARGET case TARGET-30-PALEVG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.8 years (666 days).
Specimen TARGET-30-PALEVG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a40f78e-7059-49d6-9124-c0a93863cb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALEVG-10A (Blood Derived Normal), aliquot TARGET-30-PALEVG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bdd0176-1ed6-4257-b586-b15bf94afe00

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANK1 | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs115756459; called by muse, varscan2
- LRP1B | c.13351G>C p.V4451L | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.23); catalogued as COSV67233837; called by muse, mutect2, varscan2
- OR5L2 | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 172/1277 reads (13%) | catalogued as COSV65724346; called by muse, mutect2, varscan2
- OR8B8 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 29/546 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100044974; called by muse, mutect2
- RNF17 | c.3243C>A p.F1081L | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV55042502; called by muse, mutect2, varscan2
- RP1 | c.1514G>T p.C505F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1229330495, COSV55119124; called by muse, mutect2, varscan2
- ZCCHC2 | c.2150C>A p.S717Y | Missense Mutation (SNP) | VAF 149/606 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV54035980, COSV54038737; called by muse, mutect2, varscan2
- MED12L | c.3013G>T p.A1005S | Missense Mutation (SNP) | VAF 134/712 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MED12L | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 133/709 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
